Somatic mutation profile of tumor specimen TCGA-DM-A1D7-01A (aliquot TCGA-DM-A1D7-01A-11D-A152-10) from TCGA case TCGA-DM-A1D7, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.5 years (30,142 days).
Specimen TCGA-DM-A1D7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5609c15-d696-4d59-a3ee-7610bc2b12e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D7-10A (Blood Derived Normal), aliquot TCGA-DM-A1D7-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d29282c-2a9c-415b-9cff-f8ade8289bd4

The open-access MAF lists 154 somatic variants for this specimen: 111 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 39, Splice Site 5, Nonsense Mutation 5, Frame Shift Ins 3, RNA 2, Frame Shift Del 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.7240C>T p.R2414* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as rs112550005, CM020137, COSV100355345, COSV57315468; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4265G>T p.G1422V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52221421; called by muse, mutect2, varscan2
- ABCA2 | c.5428G>T p.A1810S (on ENST00000614293; = p.A1780S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as COSV99687480; called by muse, mutect2, varscan2
- ABCG5 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs761311404, COSV53210574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS17 | c.2051C>A p.A684D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51479194, COSV99170656; called by muse, mutect2, varscan2
- ALDH3B2 | c.1125G>T p.W375C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV62428121; called by muse, mutect2, varscan2
- ALK | c.3362G>A p.G1121D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs55760835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKLE1 | c.1724G>C p.R575P (on ENST00000394458; = p.R521P on NM_152363.6) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV66730992; called by muse, mutect2, varscan2
- ANO4 | c.1119G>T p.L373F (on ENST00000392977 / NM_001286615.2; = p.L338F on NM_178826.4) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as COSV54594298; called by muse, mutect2, varscan2
- ARHGAP29 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV53111049, COSV53111080; called by muse, mutect2, varscan2
- BCLAF3 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 142/212 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.386); catalogued as COSV61413772; called by muse, mutect2, varscan2
- BNC2 | c.3287C>T p.T1096I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV66164550; called by muse, mutect2, varscan2
- BRINP1 | c.2276A>C p.K759T | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99775159; called by muse, mutect2, varscan2
- C14orf180 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407921195, COSV59557074; called by muse, mutect2, varscan2
- CACNA1H | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs768157656, COSV100672035; called by muse, varscan2
- CAMK2D | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as rs979163662, COSV56429768; called by muse, mutect2, varscan2
- CAPG | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV99809385; called by muse, mutect2, varscan2
- CATSPER3 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs778365595, COSV50945330; called by muse, mutect2, varscan2
- CCDC113 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs780838577, COSV54685884, COSV54687144; called by muse, mutect2, varscan2
- CCDC33 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs766863738, COSV51500158; called by mutect2, varscan2
- CDH10 | c.2344G>C p.G782R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV100051106; called by muse, mutect2
- CFAP298-TCP10L | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); catalogued as rs145109364; called by muse, mutect2, varscan2
- CRTAC1 | c.1439G>C p.G480A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV100085397; called by muse, mutect2
- CTNNA2 | c.2838A>T p.E946D (on ENST00000402739 / NM_001282597.3; = p.E898D on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV58149994; called by muse, mutect2, varscan2
- CTNND1 | c.1423A>C p.T475P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62383286, COSV62384699; called by muse, mutect2, varscan2
- CUBN | c.2301G>A p.E767= | Splice Region (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100913333, COSV64714677; called by muse, mutect2, varscan2
- DCLK1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV55171577, COSV55172183, COSV55184384; called by muse, mutect2, varscan2
- DENND1B | c.176+1G>A p.X59_splice | Splice Site (SNP) | VAF 62/348 reads (18%) | catalogued as COSV52463997; called by muse, mutect2, varscan2
- DMBT1 | c.7033G>A p.V2345I (on ENST00000338354 / NM_001377530.1; = p.V1588I on NM_004406.3) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs544748787, COSV57542510; called by muse, mutect2
- DNAH9 | c.11461G>T p.A3821S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as COSV52338378; called by muse, mutect2, varscan2
- DPP10 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV59683309; called by muse, mutect2, varscan2
- ENPEP | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.366); catalogued as COSV54450203; called by muse, mutect2, varscan2
- EPG5 | c.5518+2T>G p.X1840_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56348939; called by muse, mutect2, varscan2
- EPHA3 | c.1525A>T p.I509F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60703764; called by muse, mutect2, varscan2
- FBLN7 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.078); catalogued as COSV58666025; called by muse, mutect2, varscan2
- FLG | c.2344C>G p.R782G | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV64238446, COSV64241098; called by muse, mutect2, varscan2
- GAS2L3 | c.756+2T>G p.X252_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as COSV57157056; called by muse, mutect2, varscan2
- HCFC1R1 | c.374C>G p.P125R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV50187309, COSV50187497; called by muse, mutect2, varscan2
- HECW1 | c.3010C>T p.R1004W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs113884072, COSV67828314; called by muse, mutect2, varscan2
- HEXD | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV60063806; called by muse, mutect2, varscan2
- HPSE2 | c.1691G>T p.R564L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV65188152, COSV65188189; called by muse, mutect2, varscan2
- KCNE5 | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64508358, COSV64508686; called by muse, mutect2, varscan2
- KCNG4 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583609; called by muse, mutect2, varscan2
- KCNJ2 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99696329; called by muse, mutect2
- KCNU1 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV67755237; called by muse, mutect2, varscan2
- KIAA1586 | c.1379A>T p.K460M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100875340; called by muse, mutect2, varscan2
- KIF3C | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV53099093; called by muse, mutect2, varscan2
- KIF4B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391654, COSV70529106; called by muse, mutect2, varscan2
- LHFPL6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65445382; called by muse, mutect2, varscan2
- MUC20 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.432); catalogued as rs773516940, COSV57849355; called by muse, mutect2, varscan2
- N4BP2L2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57228219, COSV57228259; called by muse, mutect2, varscan2
- NEB | c.2042A>T p.Y681F | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs770440960, COSV51230883; called by muse, mutect2, varscan2
- NETO1 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.065); catalogued as rs1481068057, COSV55005800; called by muse, mutect2, varscan2
- NLRP10 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1337384075, COSV60781578; called by muse, mutect2, varscan2
- NOVA2 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611313; called by muse, mutect2
- NOX3 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV50151297; called by muse, mutect2, varscan2
- NRXN3 | c.963C>A p.D321E (on ENST00000557594 / NM_001272020.2; = p.D953E on NM_004796.6) | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV55325744; called by muse, mutect2, varscan2
- OBSCN | c.11458G>A p.V3820M | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.772); catalogued as rs371818048; called by muse, mutect2, varscan2
- OR2M3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs138010167; called by muse, mutect2, varscan2
- OR2M7 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1257087789, COSV100522510; called by muse, mutect2, varscan2
- OR4C16 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV58941760; called by muse, mutect2, varscan2
- OTOL1 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV60006639; called by muse, mutect2, varscan2
- PCDH17 | c.3016C>T p.R1006* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs73207471, COSV64973661; called by muse, mutect2, varscan2
- PCDHA13 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56496998; called by muse, mutect2, varscan2
- PCDHGA5 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as rs1330798978, COSV53917103; called by muse, mutect2, varscan2
- PRKD3 | c.1827G>T p.K609N | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52213028; called by muse, mutect2, varscan2
- PTGES3 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56273687; called by muse, mutect2, varscan2
- PTPRZ1 | c.5475G>C p.M1825I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66435645; called by muse, mutect2, varscan2
- PWP1 | c.1169-2A>T p.X390_splice | Splice Site (SNP) | VAF 30/78 reads (38%) | catalogued as COSV69832699; called by muse, mutect2
- PZP | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54359384; called by muse, mutect2, varscan2
- RELT | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV50361297; called by muse, mutect2, varscan2
- RGS3 | c.2672G>T p.G891V (on ENST00000350696 / NM_001282923.2; = p.G610V on NM_130795.4) | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100636690, COSV59522029; called by muse, mutect2, varscan2
- RIMS2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV101267312; called by muse, varscan2
- RP1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs758050819, COSV55115731; called by muse, mutect2, varscan2
- RYR2 | c.10087G>T p.A3363S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100769614; called by muse, mutect2, varscan2
- SF3B1 | c.3224G>A p.R1075K | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV59212875; called by muse, mutect2, varscan2
- SHOC2 | c.1092C>G p.H364Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV54621578; called by muse, mutect2, varscan2
- SLC24A2 | c.656T>A p.V219D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53863732; called by muse, mutect2, varscan2
- SLC5A8 | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73310593; called by muse, mutect2, varscan2
- SMAD2 | c.1350C>G p.D450E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50992828, COSV51018069; called by muse, mutect2
- SOAT2 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56857314; called by muse, mutect2, varscan2
- SOX11 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58985996, COSV58987220; called by muse, mutect2
- SOX5 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV58628047; called by muse, mutect2, varscan2
- SOX7 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767524561, COSV58730721; called by muse, mutect2, varscan2
- SPHKAP | c.2815del p.S939Pfs*31 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | catalogued as COSV60877042; called by mutect2, varscan2
- SRCAP | c.2547G>A p.M849I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs768182666, COSV52671778; called by muse, mutect2, varscan2
- ST14 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.487); catalogued as COSV53831086, COSV53832965; called by muse, mutect2, varscan2
- TLE4 | c.144T>G p.S48R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV54631268; called by muse, mutect2, varscan2
- TLL2 | c.2703G>T p.E901D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63572255; called by muse, mutect2, varscan2
- TMEM131L | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs767232587, COSV53643879; called by muse, mutect2, varscan2
- TMEM266 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV66379335; called by muse, mutect2, varscan2
- TRPC1 | c.1757+1G>A p.X586_splice (on ENST00000476941 / NM_001251845.2; = p.X552_splice on NM_003304.4) | Splice Site (SNP) | VAF 57/199 reads (29%) | catalogued as COSV56423527; called by muse, mutect2, varscan2
- TTN | c.15771A>C p.K5257N (on ENST00000591111; = p.K4330N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | PolyPhen benign (0.006); catalogued as COSV60020736; called by muse, mutect2, varscan2
- TUBA3C | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as rs766306245, COSV67139194, COSV67139325; called by muse, mutect2, varscan2
- UBFD1 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1195241371, COSV54841720; called by muse, mutect2, varscan2
- UNC79 | c.5964G>A p.M1988I (on ENST00000393151 / NM_001346218.2; = p.M1811I on NM_020818.5) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV56385046; called by muse, mutect2, varscan2
- USP34 | c.8271C>G p.S2757R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV68400787; called by muse, mutect2, varscan2
- WNT3A | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs745831522, COSV52730400; called by muse, mutect2, varscan2
- ZNF334 | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV61618535; called by muse, mutect2
- ZW10 | c.856T>A p.Y286N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52316292; called by muse, mutect2, varscan2
- APC | c.4738dup p.I1580Nfs*11 | Frame Shift Ins (INS) | VAF 40/137 reads (29%) | called by mutect2, pindel, varscan2
- OLIG3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- OSBPL8 | c.551dup p.N184Kfs*14 | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | called by mutect2, varscan2
- PCDHB9 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.9017dup p.Y3007Lfs*2 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- POTEA | c.1300C>A p.L434I (on ENST00000519951 / NM_001005365.2; = p.L388I on NM_001002920.1) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- RIMS2 | c.4088G>T p.S1363I (on ENST00000666250 / NM_001348490.2; = p.S934I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- ACR | c.72G>A p.T24= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs151269264, COSV99334539; called by muse, mutect2, varscan2
- ADD1 | c.1680C>A p.G560= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV53268683; called by muse, mutect2, varscan2
- AHNAK | c.14487C>T p.D4829= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs141073062; called by muse, mutect2, varscan2
- ANGPTL1 | c.537C>T p.Y179= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs546016893, COSV52366211; called by muse, mutect2, varscan2
- ARHGEF7 | c.2304A>G p.S768= (on ENST00000375741 / NM_001113511.2; = p.S747= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/175 reads (49%) | catalogued as COSV54542612; called by muse, mutect2, varscan2
- CATSPER3 | c.336C>T p.N112= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs749172456, COSV99254048; called by muse, mutect2, varscan2
- CDH18 | c.1989C>T p.G663= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs367628466; called by muse, mutect2, varscan2
- CENPE | c.1332A>C p.T444= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as COSV99477654; called by muse, mutect2, varscan2
- CHD7 | c.501G>A p.P167= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs770348243, COSV71109787; called by muse, mutect2, varscan2
- CRP | c.372C>T p.I124= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs753294711, COSV54812508; called by muse, mutect2, varscan2
- FRMPD4 | c.1644C>T p.G548= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV66214295; called by muse, mutect2, varscan2
- GRIK5 | c.591G>T p.R197= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV53477957; called by muse, mutect2, varscan2
- KIF17 | c.366C>T p.F122= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs367797736; called by muse, mutect2, varscan2
- MB21D2 | c.231C>T p.D77= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs144558534; called by mutect2, varscan2
- MCC | c.261C>T p.S87= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1240310647, COSV100202459; called by muse, mutect2
- MKX | c.1029T>A p.T343= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV65392083; called by muse, mutect2, varscan2
- MSN | c.270C>T p.S90= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs777718355, COSV64303210; called by muse, mutect2, varscan2
- MTUS2 | c.831C>T p.S277= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs373502341; called by muse, mutect2, varscan2
- MYOCD | c.426G>A p.V142= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV58502790; called by muse, mutect2, varscan2
- NBEAL1 | c.5932C>A p.R1978= | Silent (SNP) | VAF 112/377 reads (30%) | catalogued as COSV68915848, COSV68915999; called by muse, mutect2, varscan2
- OR5H1 | c.309G>A p.S103= | Silent (SNP) | VAF 181/510 reads (35%) | catalogued as rs779446848, COSV63401624, COSV63401900; called by muse, mutect2, varscan2
- OXGR1 | c.453T>G p.V151= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV53657434; called by muse, mutect2, varscan2
- PAPPA2 | c.1704C>T p.S568= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs372971723, COSV100867013; called by muse, mutect2, varscan2
- PCDHA6 | c.1359G>A p.P453= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs762381127, COSV100971420; called by muse, mutect2, varscan2
- PLXNB1 | c.2448G>T p.L816= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV56489242; called by muse, mutect2, varscan2
- RECQL4 | c.795C>T p.N265= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs564678543, COSV52879150; called by muse, mutect2, varscan2
- RIPK2 | c.1488C>T p.I496= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV55132645; called by muse, mutect2, varscan2
- RTN2 | c.357G>A p.P119= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs150654638; called by muse, mutect2
- SEMA4C | c.1542C>T p.D514= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100561118, COSV59690529; called by muse, mutect2, varscan2
- SLC36A3 | c.186G>T p.G62= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV58856748; called by muse, mutect2, varscan2
- SMARCAL1 | c.1701G>A p.P567= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs763289234, COSV61920892; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMTNL1 | c.1170C>T p.Y390= (on ENST00000399154; = p.Y427= on NM_001105565.2) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs570413222, COSV67699627; called by muse, mutect2, varscan2
- TACR2 | c.930C>T p.L310= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV64822167; called by muse, mutect2, varscan2
- TCERG1 | c.1971C>A p.V657= | Silent (SNP) | VAF 11/190 reads (6%) | catalogued as COSV57039297, COSV99694712; called by muse, mutect2
- TENM3 | c.7698C>T p.S2566= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs1257574702, COSV69306457; called by muse, mutect2, varscan2
- TMBIM4 | c.51C>T p.F17= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53968721; called by muse, mutect2, varscan2
- TNS1 | c.4617G>A p.K1539= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV50700826; called by muse, mutect2, varscan2
- ZFYVE9 | c.1827T>C p.N609= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV55093345; called by muse, mutect2, varscan2
- ZNFX1 | c.4999C>T p.L1667= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as COSV65596916; called by muse, mutect2, varscan2
- CD200R1 | c.68-16749G>A | Intron (SNP) | VAF 30/74 reads (41%) | catalogued as rs145811094; called by muse, mutect2, varscan2
- DCHS2 | n.6373G>A | RNA (SNP) | VAF 10/77 reads (13%) | catalogued as rs376721416; called by muse, mutect2, varscan2
- FGFR3 | c.*1062G>A | 3'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as rs773089715, COSV53400089; called by muse, mutect2, varscan2
- FOLH1B | n.1626G>C | RNA (SNP) | VAF 77/399 reads (19%) | catalogued as rs769447971; called by muse, mutect2, varscan2
